Somatic mutation profile of tumor specimen TCGA-EP-A2KB-01A (aliquot TCGA-EP-A2KB-01A-11D-A183-10) from TCGA case TCGA-EP-A2KB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.1 years (16,835 days).
Specimen TCGA-EP-A2KB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30bb4851-e7aa-4de1-8d47-cfbf4e0173cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EP-A2KB-10A (Blood Derived Normal), aliquot TCGA-EP-A2KB-10A-01D-A183-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c3f779d-2102-43dd-8d37-b2b75840b692

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, Nonsense Mutation 7, 3'UTR 3, RNA 3, Frame Shift Del 2, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.689T>C p.I230T | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as rs771884090, COSV55846971; called by muse, mutect2, varscan2
- ADAMTS5 | c.2612G>T p.G871V | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53177357, COSV53178765; called by muse, mutect2, varscan2
- ADGRL4 | c.345C>A p.C115* | Nonsense Mutation (SNP) | VAF 197/247 reads (80%) | catalogued as COSV66061422; called by muse, mutect2, varscan2
- ARAF | c.1776T>A p.D592E | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51692459; called by muse, mutect2, varscan2
- ASIC3 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV52521908; called by muse, mutect2, varscan2
- ATP8A2 | c.2375T>C p.I792T | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54950348; called by muse, mutect2, varscan2
- BAAT | c.623T>C p.L208S | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1380417991, COSV52288851; called by muse, mutect2, varscan2
- BMPER | c.1055G>T p.G352V | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51813906, COSV51817713; called by muse, mutect2, varscan2
- BTRC | c.338A>T p.N113I (on ENST00000370187 / NM_033637.4; = p.N77I on NM_003939.5) | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV64561190; called by muse, mutect2, varscan2
- CDRT15 | c.499T>C p.W167R | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.781); catalogued as rs1473126001, COSV69755503; called by muse, mutect2, varscan2
- CEP250 | c.2367G>T p.Q789H | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV61169873; called by muse, mutect2, varscan2
- CFAP45 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 221/1097 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377248471; called by muse, mutect2, varscan2
- CFAP47 | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 112/333 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52884171; called by muse, mutect2, varscan2
- CLCN1 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58369637, COSV58370162; called by muse, mutect2, varscan2
- COX5A | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.02); catalogued as COSV59279351; called by muse, mutect2, varscan2
- CUBN | c.1679G>C p.S560T | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as COSV64714937, COSV64717195; called by muse, mutect2, varscan2
- DENND4B | c.3181C>T p.L1061F | Missense Mutation (SNP) | VAF 218/388 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.076); catalogued as COSV63408999; called by muse, mutect2, varscan2
- DHX9 | c.2308C>G p.P770A | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as COSV62359419; called by muse, mutect2
- DMD | c.950T>A p.F317Y | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV55868685; called by muse, varscan2
- ERCC3 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV53426978; called by muse, mutect2, varscan2
- F5 | c.1673A>G p.Y558C | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM014861, COSV63123598; called by muse, mutect2
- FBN2 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52510725; called by muse, mutect2, varscan2
- GRM3 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64471269; called by muse, mutect2, varscan2
- IFNG | c.189T>A p.S63R | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as COSV57491196; called by muse, mutect2, varscan2
- KNTC1 | c.1953G>C p.E651D | Missense Mutation (SNP) | VAF 16/231 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV61079729, COSV61079970; called by muse, mutect2
- LRRC17 | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50864618; called by muse, mutect2, varscan2
- MARS1 | c.2555A>C p.Q852P | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56254499; called by muse, mutect2, varscan2
- MDN1 | c.14921A>C p.E4974A | Missense Mutation (SNP) | VAF 138/291 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV65521132; called by muse, mutect2, varscan2
- MMGT1 | c.99A>T p.L33F | Missense Mutation (SNP) | VAF 219/439 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV60003251; called by muse, mutect2, varscan2
- MPO | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1271546630, COSV56563552; called by muse, mutect2
- NCAN | c.3702C>A p.Y1234* | Nonsense Mutation (SNP) | VAF 56/117 reads (48%) | catalogued as COSV53050593; called by muse, mutect2, varscan2
- OR2T3 | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 170/558 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV62082383; called by muse, mutect2, varscan2
- PAM | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57212653; called by muse, mutect2, varscan2
- PCDHB11 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 116/246 reads (47%) | catalogued as COSV53378219, COSV53378351; called by muse, mutect2, varscan2
- PCDHB15 | c.1451C>G p.A484G | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); catalogued as COSV50916967; called by muse, mutect2, varscan2
- PCDHGA4 | c.1190T>C p.I397T | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV53941772; called by muse, mutect2, varscan2
- PDCD6IP | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 51/1068 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV56242981; called by muse, mutect2
- PHF21B | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57558075; called by muse, mutect2, varscan2
- PRR23A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs1335482305, COSV67214138; called by muse, mutect2, varscan2
- RASSF9 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 36/104 reads (35%) | catalogued as rs1053694318, COSV63432565; called by muse, mutect2, varscan2
- RBM47 | c.1453G>C p.D485H (on ENST00000295971 / NM_001098634.2; = p.D416H on NM_019027.4) | Missense Mutation (SNP) | VAF 114/147 reads (78%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.275); catalogued as COSV55934598; called by muse, mutect2, varscan2
- RHPN2 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV54278441; called by muse, mutect2, varscan2
- RICTOR | c.3474A>T p.Q1158H | Missense Mutation (SNP) | VAF 178/406 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV57121489; called by muse, mutect2, varscan2
- RNF128 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 71/192 reads (37%) | catalogued as COSV55250900; called by muse, mutect2, varscan2
- RPS6KA3 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65387729; called by muse, mutect2
- SCP2D1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 86/181 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.299); catalogued as COSV53857221; called by muse, mutect2, varscan2
- SLC45A4 | c.1461G>T p.E487D (on ENST00000517878 / NM_001286646.2; = p.E436D on NM_001080431.2) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV50137922; called by muse, mutect2, varscan2
- SLITRK1 | c.1662C>G p.S554R | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as COSV65675425, COSV65675711; called by muse, mutect2, varscan2
- SNAP29 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 100/141 reads (71%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV53142569; called by muse, mutect2, varscan2
- SOX3 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV65168191; called by muse, mutect2, varscan2
- SPATA19 | c.195G>C p.Q65H | Missense Mutation (SNP) | VAF 99/164 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as COSV54483215; called by muse, mutect2, varscan2
- SPECC1 | c.2894G>A p.R965H | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs778718188, COSV54957478; called by muse, mutect2, varscan2
- SPTB | c.5383G>A p.A1795T | Missense Mutation (SNP) | VAF 64/73 reads (88%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.812); catalogued as rs749332448; called by muse, varscan2
- SYT10 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 215/563 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV57340075; called by muse, mutect2, varscan2
- TASOR | c.4108C>G p.Q1370E (on ENST00000355628 / NM_001365636.2; = p.Q994E on NM_015224.3) | Missense Mutation (SNP) | VAF 156/302 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as rs753621253, COSV58303593; called by muse, mutect2, varscan2
- TCP11L2 | c.1377G>A p.M459I | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54429910; called by muse, mutect2, varscan2
- TFAP2D | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.18); catalogued as rs905669915, COSV50414523; called by muse, mutect2, varscan2
- TMEM131L | c.2728A>G p.S910G | Missense Mutation (SNP) | VAF 138/160 reads (86%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1055093698, COSV53644086; called by muse, mutect2, varscan2
- TPO | c.482G>T p.R161I | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1213524627, COSV61101073; called by muse, mutect2, varscan2
- TSPEAR | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs370848096, COSV59958847; called by muse, mutect2, varscan2
- XAB2 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV64321642; called by muse, mutect2, varscan2
- ZNF223 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 49/127 reads (39%) | catalogued as COSV71571879; called by muse, mutect2, varscan2
- ZNF710 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.3); catalogued as COSV51562925; called by muse, mutect2, varscan2
- ARID1A | c.6116_6117insT p.Q2039Hfs*60 | Frame Shift Ins (INS) | VAF 111/185 reads (60%) | called by mutect2, pindel, varscan2
- CADM2 | c.337del p.T113Lfs*29 (on ENST00000407528 / NM_001167674.2; = p.T115Lfs*29 on NM_153184.4) | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | called by pindel, varscan2
- CDKL5 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 234/440 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- HNF1B | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 159/396 reads (40%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.3798del p.S1267Afs*25 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- TSHR | c.317+8C>A | Splice Region (SNP) | VAF 12/32 reads (38%) | called by muse, varscan2
- AKAIN1 | c.153C>T p.N51= | Silent (SNP) | VAF 128/226 reads (57%) | catalogued as COSV71420219; called by muse, varscan2
- CCT8L2 | c.1440G>T p.V480= | Silent (SNP) | VAF 106/148 reads (72%) | catalogued as COSV63461634, COSV63462331; called by muse, mutect2, varscan2
- CR1L | c.1566C>T p.I522= | Silent (SNP) | VAF 73/507 reads (14%) | catalogued as rs1230663963, COSV54325638; called by muse, mutect2, varscan2
- DEF8 | c.483C>A p.P161= (on ENST00000268676 / NM_207514.3; = p.P100= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 211/248 reads (85%) | catalogued as COSV51918839, COSV51919030; called by muse, mutect2, varscan2
- FBLN1 | c.1365C>T p.A455= | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as COSV53046840; called by muse, mutect2, varscan2
- HEPHL1 | c.1221C>T p.N407= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs557012995, COSV59892696; called by muse, mutect2, varscan2
- JARID2 | c.1842C>T p.I614= | Silent (SNP) | VAF 62/141 reads (44%) | catalogued as COSV59188919, COSV59195849; called by muse, mutect2, varscan2
- LANCL1 | c.48C>G p.S16= | Silent (SNP) | VAF 151/297 reads (51%) | catalogued as COSV52065066; called by muse, mutect2, varscan2
- LIN7C | c.51A>G p.A17= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV53415352, COSV53415435; called by muse, mutect2, varscan2
- MSANTD3 | c.450C>T p.C150= | Silent (SNP) | VAF 80/181 reads (44%) | catalogued as rs755534896, COSV100614960, COSV58490778; called by muse, mutect2, varscan2
- MUC4 | c.1131C>G p.T377= | Silent (SNP) | VAF 106/356 reads (30%) | catalogued as rs1001914501, COSV62148332; called by muse, mutect2, varscan2
- NKX6-3 | c.795C>T p.V265= (on ENST00000518699 / NM_001364841.2; = p.V135= on NM_152568.3) | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs977838689, COSV72895107; called by muse, varscan2
- NPPC | c.372G>A p.L124= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV54945386; called by muse, mutect2, varscan2
- RGPD4 | c.3147A>G p.E1049= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV61746352; called by muse, mutect2, varscan2
- SLC2A4RG | c.667C>T p.L223= | Silent (SNP) | VAF 59/128 reads (46%) | catalogued as rs779690496, COSV55509738; called by muse, mutect2, varscan2
- TENM4 | c.3495G>T p.A1165= | Silent (SNP) | VAF 124/335 reads (37%) | catalogued as rs369844183, COSV53613840; called by muse, mutect2, varscan2
- TH | c.315G>A p.E105= (on ENST00000381178 / NM_199292.3; = p.E74= on NM_000360.4) | Silent (SNP) | VAF 83/146 reads (57%) | catalogued as COSV60767288; called by muse, mutect2, varscan2
- TYK2 | c.847C>T p.L283= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV53387086; called by muse, mutect2, varscan2
- ZNF10 | c.45C>G p.T15= | Silent (SNP) | VAF 79/191 reads (41%) | catalogued as COSV50212250; called by muse, mutect2, varscan2
- ZSWIM6 | c.201G>T p.P67= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV99405491; called by muse, mutect2, varscan2
- AC092718.9 | n.71T>C | RNA (SNP) | VAF 67/83 reads (81%) | catalogued as rs546322359; called by muse, mutect2, varscan2
- ARHGEF2 | c.*5del | 3'UTR (DEL) | VAF 21/108 reads (19%) | catalogued as COSV100559823; called by mutect2, pindel, varscan2
- CCDC144NL | n.686C>T | RNA (SNP) | VAF 62/175 reads (35%) | catalogued as rs79678106; called by muse, mutect2, varscan2
- GCNT1 | c.*685del | 3'UTR (DEL) | VAF 66/177 reads (37%) | called by mutect2, pindel, varscan2
- OTUD6A | c.*136C>A | 3'UTR (SNP) | VAF 49/95 reads (52%) | catalogued as COSV100611105; called by muse, mutect2, varscan2
- RPGR | c.2520+1332G>T | Intron (SNP) | VAF 378/754 reads (50%) | catalogued as rs1375381631, COSV58834921; called by muse, mutect2
- SLITRK2 | chrX:145828926 T>A | 3'Flank (SNP) | VAF 165/495 reads (33%) | catalogued as COSV100158308; called by muse, mutect2, varscan2
- ZNF658B | n.2543C>T | RNA (SNP) | VAF 161/347 reads (46%) | called by muse, mutect2, varscan2
